Gene-level copy-number profile of tumor specimen TCGA-09-2054-01A from TCGA case TCGA-09-2054, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 58.3 years (21,285 days).
Specimen TCGA-09-2054-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.47e0a74c-6d83-40ba-8d6d-f04add97433b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-09-2054-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a2b8c2bb-266e-4665-957e-568e165bf4ed

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,531; copy number 2: 20,567; copy number 3: 23,325; copy number 4: 8,665; copy number 5: 4,444; copy number 6: 293; copy number 7: 64; copy number 8: 656; copy number 9: 191; copy number 11: 74.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-09-2054-01): tumor purity 0.87, ploidy 2.91, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 983 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:29,841,187–37,157,065, 96 genes, copy number 7–8 (within-gene range 5–8) (broad region; genes not listed).
- chr9:137,188,660–137,870,016, 36 genes, copy number 7 (within-gene range 4–7): SSNA1, TPRN, TMEM203, NDOR1, BX255925.3, RNF208, CYSRT1, RNF224, SLC34A3, TUBB4B, FAM166A, STPG3-AS1, STPG3, NELFB, TOR4A, BX255925.2, BX255925.1, BX255925.4, NRARP, EXD3, NOXA1, ENTPD8, NSMF, MIR7114, PNPLA7, MRPL41, DPH7, ZMYND19, ARRDC1, AL590627.2, ARRDC1-AS1, EHMT1, Metazoa_SRP, SETP5, AL590627.1, MIR602.
- chr18:2,506,628–5,004,537, 54 genes, copy number 11: AP005136.4, METTL4, AP005136.1, AP005136.3, AP005136.2, NDC80, KATNBL1P3, Y_RNA, RNU6-340P, CBX3P2, SMCHD1, AP001011.1, Y_RNA, EMILIN2, LPIN2, AP000919.3, CHORDC1P4, AP000919.1, AP000919.2, SNRPCP4, AP005431.1, SNORA70, MYOM1, RNU7-25P, AP005329.2, AP005329.3, MYL12A, AP005329.1, MYL12B, AP001025.1, LINC01895, RPL31P59, IGLJCOR18, RPL21P127, TGIF1, BOD1P1, GAPLINC, DLGAP1, RN7SL39P, AP002472.1, DLGAP1-AS1, DLGAP1-AS2, AP002478.1, AP002478.2, DLGAP1-AS3, MIR6718, RNU6-831P, DLGAP1-AS4, GAPDHP66, DLGAP1-AS5, AP005208.1, ELOCP27, AP005203.1, PPIAP14.
- chr18:72,536,680–74,298,662, 20 genes, copy number 11: CBLN2, HNRNPA1P11, NETO1, AC023301.1, RNA5SP460, MIR548AV, AC091138.1, LINC02864, LINC02582, AC079070.1, RN7SL401P, AC090125.1, AC010947.1, AC090125.2, FBXO15, TIMM21, AC090398.1, RN7SL551P, CYB5A, AC090398.2.
- chr19:7,944,241–22,091,480, 764 genes, copy number 8–9 (within-gene range 5–9) (broad region; genes not listed).
- chr20:13,714,322–13,996,443, 4 genes, copy number 7 (within-gene range 2–7): ESF1, NDUFAF5, SEL1L2, RNU6-278P.
- chr20:14,003,508–14,758,056, 9 genes, copy number 7: RPS3P1, AIMP1P1, RN7SL864P, FLRT3, RNU6-228P, AL121582.1, RNF11P2, MACROD2-IT1, RPS10P2.

Autosomal genes at a single copy (total copy number 1): 1,531. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
